Surgical pathology report (de-identified scan), TCGA case TCGA-56-7223, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-7223-01A (Primary Tumor).

[page 1 of 3]
ADDENDUM SURGICAL PATHOLOGY REPORT

Addendum Information:

This addendum is issued to add information about the additional portion of pericardial tissue. The diagnosis remains unchanged.

Diagnosis:

A. -I.) LUNG, RIGHT, MIDDLE AND LOWER LOBES, HILAR (N10R), INTERLOBAR (N11R X 2), SUBCARINAL (N7), PARAESOPHAGEAL (N8), AND LOWER PARATRACHEAL (N4R) LYMPH NODES, BILOBECTOMY WITH REGIONAL LYMPHADENECTOMY:

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.**
- 14 cm in greatest dimension.**
- Visceral pleural invasion: Not identified.**
- MARGIN STATUS: NEGATIVE.**
- Tumor is 0.5 cm from the bronchial margin.**
- Vascular and parenchymal margins uninvolved by invasive carcinoma.**
- LYMPHOVASCULAR INVASION: NOT IDENTIFIED.**
- ONE (N10R) OF TWENTY-NINE TOTAL LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (1/29).**
- PERICARDIAL TISSUE, NEGATIVE FOR TUMOR.**

PATHOLOGIC STAGING SUMMARY:

Type and grade: Squamous cell carcinoma, poorly differentiated.

Primary tumor: pT3 (14 cm in maximum dimension).

Regional lymph nodes: pN1 (one peribronchial lymph node (N10R) out of twenty-nine lymph nodes, positive for metastatic carcinoma, 1/29).

Distant metastasis: pMX.

Pathologic stage: IIIA.

Lymphovascular invasion: Not identified.

[page 2 of 3]
ADDENDUM SURGICAL PATHOLOGY REPORT

Margin status: R0 (tumor is 0.5 cm from the bronchial margin).

COMMENT: Elastic stain, performed with adequate control confirms the absence of visceral pleura invasion.

Findings discussed with Dr.

[page 3 of 3]
ADDENDUM SURGICAL PATHOLOGY REPORT

Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, [REDACTED])

Specimen:	Lung, middle and lower lobes.
Procedure:	Bilobectomy.
Specimen integrity:	Intact.
Specimen laterality:	Right.

TUMOR FEATURES:

Tumor site:	Lower lobe.
Tumor size:	
Greatest dimension:	14 cm.
Additional dimensions:	12 x 8 cm.
Tumor focality:	Unifocal.
Histologic type:	Squamous cell carcinoma.
Histologic grade:	Poorly differentiated (G3).
Visceral pleural invasion:	Not identified.
Tumor extension:	Not applicable.

MARGINS:

Bronchial margin:	R0 (negative).
Vascular margin:	Tumor is 0.5 cm from bronchial margin.
Parenchymal margin:	Uninvolved by invasive carcinoma.
Parietal pleural margin:	Uninvolved by invasive carcinoma.
Chest wall margin:	Not applicable.
Medial pericardial margin:	Not applicable.
Treatment effect:	Uninvolved by invasive carcinoma.

Lymphovascular invasion:	Not identified.
Lymph nodes:	One peribronchial (N10R) lymph node out of twenty-nine total lymph nodes positive for metastasis (1/29).

PATHOLOGIC STAGING SUMMARY:

Primary tumor:	pT3 (14 cm in greatest dimension).
Regional lymph nodes:	pN1 (1/29 total lymph nodes).
Distant metastasis:	pMX.
Pathologic stage:	IIIA.
Margin status:	R0 (tumor is 0.5cm from the bronchial margin).

Source: NCI Genomic Data Commons file 37d5672c-4680-449c-a8bb-a42da42ab6f2 (TCGA-56-7223.58B457C7-7273-4CC2-8EB9-5D14C01EBB45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).